Somatic mutation profile of tumor specimen 0DWNTP from CCDI case PBCPLU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 14.2 years (5,185 days).
Specimen 0DWNTP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01dd218b-de88-4a2b-9aa7-61c39c71f0ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWNRA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/367dfb30-90d4-41df-801c-33e4c58d3551

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNK6 | c.859G>A p.V287M | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as COSV54581344; called by muse, mutect2, varscan2
- NTM | c.224T>G p.L75R | Missense Mutation (SNP) | VAF 53/499 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66177599; called by muse, mutect2, varscan2
- C4orf54 | c.1807G>T p.V603L | Missense Mutation (SNP) | VAF 31/287 reads (11%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- FTO | c.943C>G p.P315A | Missense Mutation (SNP) | VAF 25/878 reads (3%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.953); called by muse, mutect2
- PRODH2 | c.856C>A p.Q286K (on ENST00000301175; = p.Q210K on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- NEK9 | c.828G>A p.Q276= | Silent (SNP) | VAF 32/325 reads (10%) | catalogued as rs751357379; called by muse, mutect2
- NPAP1 | c.1857C>A p.V619= | Silent (SNP) | VAF 41/165 reads (25%) | called by muse, mutect2, varscan2
- PREX2 | c.4604+74G>A | Intron (SNP) | VAF 10/158 reads (6%) | catalogued as rs1337531020, COSV55764211; called by muse, mutect2
